Somatic mutation profile of tumor specimen TCGA-A6-2681-01A (aliquot TCGA-A6-2681-01A-01D-1408-10) from TCGA case TCGA-A6-2681, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 73.7 years (26,929 days).
Specimen TCGA-A6-2681-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bd6fdef5-ec03-43cb-8610-9dfcb1400082.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A6-2681-10A (Blood Derived Normal), aliquot TCGA-A6-2681-10A-01D-2188-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0b8242a3-ff94-4f7d-af59-2bc303dee558

The open-access MAF lists 157 somatic variants for this specimen: 114 protein-altering or splice-affecting, 33 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 104, Silent 33, Nonsense Mutation 5, 3'UTR 3, Splice Region 3, Intron 3, RNA 2, Frame Shift Ins 1, 5'UTR 1, 5'Flank 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCD1 | c.421G>A p.A141T | Missense Mutation (SNP) | VAF 32/73 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs193922097, CM950030, COSV54385597; ClinVar: pathogenic; called by muse, mutect2, varscan2
- APC | c.904C>T p.R302* | Nonsense Mutation (SNP) | VAF 9/24 reads (38%) | catalogued as rs137854568, CM910029, COSV57324169; ClinVar: pathogenic; called by muse, mutect2, varscan2
- COL1A1 | c.2299G>A p.G767S | Missense Mutation (SNP) | VAF 22/32 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs72651658, CM940291, COSV56809727; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 40/70 reads (57%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABLIM3 | c.457G>A p.G153R | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs186503737, COSV100448095; called by muse, mutect2, varscan2
- AC006059.2 | c.502C>T p.R168W | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs762089355, COSV59609849; called by muse, mutect2, varscan2
- ACTRT3 | c.290C>T p.P97L | Missense Mutation (SNP) | VAF 32/77 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs776125776, COSV100377511; called by muse, mutect2, varscan2
- ADAM22 | c.1079T>A p.F360Y | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.018); catalogued as COSV55974515; called by mutect2, varscan2
- ADCY1 | c.2504G>T p.R835L | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.229); catalogued as COSV52030315, COSV52036132, COSV99812390; called by muse, mutect2, varscan2
- ADCY9 | c.635G>A p.R212Q | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs1441874703, COSV99570311; called by muse, mutect2, varscan2
- ADNP | c.1198T>C p.S400P | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT tolerated (0.1); PolyPhen benign (0.027); catalogued as COSV100823785; called by muse, mutect2, varscan2
- AL159163.1 | c.508G>A p.V170I | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious, low confidence (0); catalogued as rs373393079; called by muse, mutect2, varscan2
- AMER1 | c.1438G>T p.E480* | Nonsense Mutation (SNP) | VAF 21/77 reads (27%) | catalogued as COSV100366607, COSV57655438; called by muse, mutect2, varscan2
- ANK2 | c.3005C>T p.T1002M | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.843); catalogued as rs575960435, COSV100002482; called by muse, mutect2, varscan2
- ANK2 | c.4445C>A p.T1482K | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV100002484; called by muse, mutect2, varscan2
- ANKRD16 | c.725C>T p.A242V | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT tolerated (0.06); PolyPhen benign (0.294); catalogued as rs774503557, COSV99510466; called by muse, mutect2, varscan2
- ATP1A1 | c.1702G>T p.G568W | Missense Mutation (SNP) | VAF 5/56 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99814591; called by muse, mutect2
- BTF3 | c.286G>C p.G96R (on ENST00000380591 / NM_001037637.1; = p.G52R on NM_001207.4) | Missense Mutation (SNP) | VAF 31/88 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.125); catalogued as COSV60063344; called by muse, mutect2, varscan2
- C1orf21 | c.242G>A p.G81E | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV99334884; called by muse, mutect2, varscan2
- C3orf52 | c.598A>G p.I200V | Missense Mutation (SNP) | VAF 18/97 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99332515; called by muse, mutect2, varscan2
- CCDC80 | c.401C>T p.S134L | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.039); catalogued as rs770365462, COSV99244963; called by muse, mutect2, varscan2
- CD53 | c.224T>C p.I75T | Missense Mutation (SNP) | VAF 17/149 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV99602274; called by muse, mutect2, varscan2
- CDH8 | c.1157A>G p.D386G | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100182349, COSV100182594; called by muse, mutect2, varscan2
- CERS6 | c.416T>G p.F139C | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.981); catalogued as rs1467012286, COSV59829032; called by muse, mutect2
- CFAP77 | c.923G>A p.R308H | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs138982113; called by muse, mutect2, varscan2
- CHGA | c.992G>A p.R331Q | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.42); PolyPhen benign (0.013); catalogued as rs552215557, COSV50894810; called by muse, mutect2, varscan2
- CNTN4 | c.508C>T p.R170C | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs765118168, COSV100638650; called by muse, mutect2, varscan2
- COL6A6 | c.3222T>A p.F1074L | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT tolerated (0.3); PolyPhen benign (0.037); catalogued as COSV100650472; called by muse, mutect2, varscan2
- CSNK1G3 | c.710A>G p.H237R | Missense Mutation (SNP) | VAF 46/111 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100631602; called by muse, mutect2, varscan2
- CYP4F22 | c.50C>T p.T17M | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.732); catalogued as rs773295754, COSV99512903; called by muse, mutect2, varscan2
- DBT | c.771A>C p.K257N | Missense Mutation (SNP) | VAF 18/101 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.024); catalogued as CD126896, COSV64495323; called by muse, mutect2, varscan2
- DDX46 | c.643A>C p.K215Q | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.328); catalogued as COSV100844901; called by muse, mutect2, varscan2
- DNAH9 | c.1405G>A p.G469S | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.939); catalogued as rs559139037, COSV99306576; called by muse, mutect2, varscan2
- DNAJC3 | c.190G>A p.V64I | Missense Mutation (SNP) | VAF 61/107 reads (57%) | SIFT tolerated (0.4); PolyPhen benign (0.015); catalogued as rs746997401, COSV65131190; called by muse, varscan2
- ECPAS | c.3297T>A p.F1099L | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV99398652; called by muse, mutect2, varscan2
- ELP1 | c.1136G>A p.R379Q | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.886); catalogued as rs762459195, COSV65897827; called by muse, mutect2, varscan2
- EPB41L1 | c.1826C>T p.T609M | Missense Mutation (SNP) | VAF 27/46 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99151184; called by muse, mutect2, varscan2
- ERG | c.484G>A p.V162I | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated (0.59); PolyPhen benign (0.09); catalogued as rs552037654, COSV55726607; called by muse, mutect2, varscan2
- ESF1 | c.2054C>T p.S685L | Missense Mutation (SNP) | VAF 64/134 reads (48%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.978); catalogued as rs552139164, COSV52524875, COSV99176278, COSV99176414; called by muse, mutect2, varscan2
- FAM117A | c.369G>A p.T123= | Splice Region (SNP) | VAF 17/28 reads (61%) | catalogued as rs774309596, COSV53630870; called by muse, mutect2, varscan2
- FBXO40 | c.943G>A p.G315R | Missense Mutation (SNP) | VAF 18/33 reads (55%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV100573220; called by muse, mutect2, varscan2
- FFAR3 | c.554G>A p.R185Q | Missense Mutation (SNP) | VAF 43/72 reads (60%) | SIFT tolerated (0.1); PolyPhen probably damaging (1); catalogued as rs138338117; called by muse, mutect2, varscan2
- FGF3 | c.431G>A p.R144H | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.782); catalogued as rs781807006, COSV100490237; called by muse, mutect2, varscan2
- FLNA | c.7354G>A p.V2452M (on ENST00000369850 / NM_001110556.2; = p.V2444M on NM_001456.3) | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as rs782450850, COSV100774869; called by muse, mutect2, varscan2
- FSD1 | c.1379C>T p.T460M | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated (0.46); PolyPhen benign (0.019); catalogued as rs375153495, COSV99696861; called by muse, mutect2, varscan2
- GRID2 | c.169A>G p.I57V | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.956); catalogued as COSV99942692; called by muse, mutect2, varscan2
- HCFC1 | c.2453T>C p.V818A | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.371); catalogued as COSV100129415; called by muse, mutect2, varscan2
- HOXA9 | c.326G>A p.R109H | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.866); catalogued as rs1057051769; called by muse, mutect2
- IPO9 | c.629G>A p.R210Q | Missense Mutation (SNP) | VAF 12/154 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.288); catalogued as COSV100843484; called by muse, mutect2
- ITPRIPL2 | c.1586G>T p.G529V | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.881); catalogued as COSV67347523; called by muse, mutect2, varscan2
- KCNV1 | c.1285G>T p.D429Y | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV52084541, COSV99819212; called by muse, mutect2, varscan2
- KHDC4 | c.1295C>G p.A432G | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.685); catalogued as COSV64165310; called by muse, varscan2
- KIAA1549L | c.4869G>A p.P1623= (on ENST00000321505; = p.P1920= on NM_012194.3) | Splice Region (SNP) | VAF 11/40 reads (28%) | catalogued as rs771446533, COSV58586351; called by muse, mutect2, varscan2
- KIF2B | c.107G>A p.R36H | Missense Mutation (SNP) | VAF 19/30 reads (63%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.479); catalogued as rs754482684, COSV52128242; called by muse, mutect2, varscan2
- KLK6 | c.19G>C p.V7L | Missense Mutation (SNP) | VAF 55/75 reads (73%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as rs1274193044, COSV59565414; called by muse, mutect2, varscan2
- LAMP1 | c.752C>T p.T251M | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.462); catalogued as rs370286796; called by muse, mutect2, varscan2
- LCK | c.1077T>A p.N359K | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.943); catalogued as COSV100287826; called by muse, mutect2, varscan2
- LDLRAD3 | c.592C>T p.R198W | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs897155198, COSV100214821; called by muse, mutect2, varscan2
- LOXHD1 | c.152C>T p.T51M | Missense Mutation (SNP) | VAF 15/25 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs755538686, COSV71601090; called by muse, mutect2, varscan2
- LRFN2 | c.1940C>T p.P647L | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs776997956, COSV57828761; called by muse, mutect2, varscan2
- LYST | c.3103A>C p.K1035Q | Missense Mutation (SNP) | VAF 9/122 reads (7%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.05); catalogued as COSV101089814; called by muse, mutect2
- MAGEE2 | c.699G>A p.M233I | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.308); catalogued as COSV100973152; called by muse, mutect2, varscan2
- MAP3K21 | c.860T>C p.I287T | Missense Mutation (SNP) | VAF 20/37 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100786286; called by muse, mutect2, varscan2
- MED8 | c.693G>T p.Q231H | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT tolerated (0.17); PolyPhen benign (0.037); catalogued as COSV51940698; called by muse, mutect2, varscan2
- MGAT5B | c.833C>T p.A278V | Missense Mutation (SNP) | VAF 14/19 reads (74%) | SIFT tolerated (0.29); PolyPhen benign (0.046); catalogued as COSV100048409; called by muse, mutect2, varscan2
- MICAL2 | c.4412G>A p.R1471Q | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.003); catalogued as rs543193412, COSV56286025; called by muse, mutect2, varscan2
- MTIF2 | c.155C>A p.P52H | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.55); PolyPhen benign (0.125); catalogued as COSV99709215; called by muse, mutect2, varscan2
- NDST3 | c.26G>T p.R9I | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.027); catalogued as COSV99630972; called by muse, mutect2, varscan2
- NUDT10 | c.131G>A p.R44H | Missense Mutation (SNP) | VAF 50/147 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.274); catalogued as rs782024566, COSV62854073; called by muse, varscan2
- OR10G3 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs748283418, COSV100336120; called by muse, mutect2, varscan2
- OR51Q1 | c.456C>A p.C152* | Nonsense Mutation (SNP) | VAF 47/117 reads (40%) | catalogued as COSV100333002; called by muse, mutect2, varscan2
- OR56A1 | c.912G>T p.Q304H | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.046); catalogued as COSV100360507; called by muse, mutect2, varscan2
- OR56A4 | c.301C>G p.L101V | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.976); catalogued as COSV100417609; called by muse, mutect2, varscan2
- OR6F1 | c.739G>A p.V247M | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs369128749; called by muse, mutect2, varscan2
- PCDHB13 | c.2185G>A p.E729K | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.007); catalogued as COSV53394849; called by muse, mutect2, varscan2
- PCDHB14 | c.1318C>A p.L440M | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.811); catalogued as COSV99506063; called by muse, mutect2, varscan2
- PCDHB7 | c.2359T>A p.F787I | Missense Mutation (SNP) | VAF 34/226 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.027); catalogued as COSV99177116; called by muse, mutect2
- PCDHB7 | c.2361T>A p.F787L | Missense Mutation (SNP) | VAF 36/228 reads (16%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.005); catalogued as COSV99177117; called by muse, mutect2
- PDE5A | c.608G>T p.R203L | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.731); catalogued as COSV99308869; called by muse, mutect2, varscan2
- PEAR1 | c.1603A>G p.S535G | Missense Mutation (SNP) | VAF 20/30 reads (67%) | SIFT tolerated (0.22); PolyPhen benign (0.039); catalogued as COSV52773430, COSV99441759; called by muse, mutect2, varscan2
- PPP1R11 | c.70G>A p.E24K | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.992); catalogued as COSV99748513; called by muse, mutect2, varscan2
- PTPRC | c.2077C>T p.R693C | Missense Mutation (SNP) | VAF 31/54 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100722805; called by muse, mutect2, varscan2
- RBMXL2 | c.886C>T p.R296W | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs376176065; called by muse, mutect2, varscan2
- RBMXL2 | c.1132C>T p.R378C | Missense Mutation (SNP) | VAF 28/54 reads (52%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); catalogued as rs1247788219, COSV100182324; called by muse, mutect2, varscan2
- RIMBP2 | c.814C>G p.H272D | Missense Mutation (SNP) | VAF 35/99 reads (35%) | SIFT tolerated (0.57); PolyPhen benign (0.01); catalogued as COSV99899870; called by muse, mutect2, varscan2
- RIN2 | c.2290G>C p.D764H (on ENST00000255006 / NM_001242581.1; = p.D715H on NM_018993.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV99657388; called by muse, mutect2
- RLIM | c.776C>T p.T259M | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs1256772140, COSV60329501; called by muse, mutect2, varscan2
- RNF170 | c.472G>T p.D158Y | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.73); catalogued as COSV99533820; called by muse, mutect2, varscan2
- RTL1 | c.1520G>A p.R507H | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs752460061, COSV66016688; called by muse, mutect2, varscan2
- RYR3 | c.10153G>A p.D3385N (on ENST00000389232; = p.D3386N on NM_001036.6) | Missense Mutation (SNP) | VAF 16/19 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs753111350, COSV66788227; called by muse, mutect2, varscan2
- SAMD9 | c.3445C>A p.L1149I | Missense Mutation (SNP) | VAF 26/157 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.563); catalogued as COSV101180300; called by muse, mutect2, varscan2
- SDK1 | c.3440G>A p.R1147Q | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV67360016, COSV67379281; called by muse, mutect2, varscan2
- SH3GL2 | c.493C>T p.R165C | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1180303494, COSV66047769, COSV66055997; called by muse, mutect2, varscan2
- SHISA2 | c.379G>A p.A127T | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs779132447, COSV60112222; called by muse, mutect2, varscan2
- SLC34A2 | c.1945G>T p.E649* | Nonsense Mutation (SNP) | VAF 7/27 reads (26%) | catalogued as COSV101158401, COSV65942977; called by muse, mutect2, varscan2
- SLC45A3 | c.814C>T p.R272C | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs370670814, COSV65655264; called by muse, mutect2, varscan2
- SLC6A12 | c.1547C>A p.S516Y | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.366); catalogued as COSV100675151, COSV62885203; called by muse, mutect2, varscan2
- SMAD3 | c.127A>T p.K43* | Nonsense Mutation (SNP) | VAF 11/20 reads (55%) | catalogued as COSV100529187, COSV59287541; called by muse, mutect2, varscan2
- SPANXD | c.149T>C p.I50T | Missense Mutation (SNP) | VAF 247/547 reads (45%) | SIFT tolerated (0.26); PolyPhen benign (0.006); catalogued as COSV65152505; called by muse, mutect2, varscan2
- SPTB | c.4376G>A p.R1459Q | Missense Mutation (SNP) | VAF 17/26 reads (65%) | SIFT tolerated (0.16); PolyPhen benign (0.183); catalogued as rs148127231; called by muse, mutect2, varscan2
- SYNE3 | c.1088C>T p.A363V | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as rs142727232; called by muse, mutect2, varscan2
- TCF7L2 | c.1462C>T p.R488C (on ENST00000355995 / NM_001367943.1; = p.R465C on NM_030756.5) | Missense Mutation (SNP) | VAF 34/71 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.8); catalogued as rs1264066389, COSV53335962, COSV53336193; called by muse, mutect2, varscan2
- TIAM1 | c.1619C>T p.T540I | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99736453; called by muse, mutect2, varscan2
- TLE3 | c.1162G>A p.A388T | Missense Mutation (SNP) | VAF 12/18 reads (67%) | SIFT tolerated (0.09); PolyPhen benign (0.094); catalogued as rs765874326, COSV100450578; called by muse, mutect2, varscan2
- TMEM30A | c.851C>T p.P284L | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.371); catalogued as COSV100034947; called by muse, mutect2
- TP53 | c.434T>G p.L145R | Missense Mutation (SNP) | VAF 22/28 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV52676080, COSV52724970, COSV52728973; called by muse, mutect2, varscan2
- TTLL6 | c.1217T>A p.L406Q (on ENST00000393382 / NM_001130918.3; = p.L99Q on NM_173623.3) | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64976904; called by muse, mutect2, varscan2
- UBE2F | c.150T>C p.C50= | Splice Region (SNP) | VAF 3/37 reads (8%) | catalogued as COSV99800328; called by muse, mutect2
- ZNF275 | c.835G>A p.G279R | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.921); catalogued as rs782458088, COSV100936333; called by muse, mutect2, varscan2
- ZNF334 | c.1931C>T p.T644I | Missense Mutation (SNP) | VAF 44/200 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.076); catalogued as rs1370473557, COSV100749127; called by muse, mutect2, varscan2
- ZNF559 | c.1462A>T p.T488S | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.47); catalogued as COSV100416603; called by muse, mutect2, varscan2
- MAGEC1 | c.2200del p.E734Rfs*11 | Frame Shift Del (DEL) | VAF 27/63 reads (43%) | called by mutect2, pindel, varscan2
- OBSCN | c.15694dup p.S5232Ffs*24 | Frame Shift Ins (INS) | VAF 9/51 reads (18%) | called by mutect2, pindel, varscan2
- ZNF140 | c.4T>C p.S2P | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0.031); called by muse, varscan2
- ADAMTS16 | c.1596C>T p.D532= | Silent (SNP) | VAF 19/45 reads (42%) | catalogued as COSV56993939; called by muse, mutect2, varscan2
- AGBL5 | c.1935C>A p.G645= | Silent (SNP) | VAF 4/30 reads (13%) | catalogued as COSV100549192; called by muse, mutect2, varscan2
- APOBEC3C | c.84C>T p.N28= | Silent (SNP) | VAF 11/17 reads (65%) | catalogued as rs773172607, COSV100815175; called by muse, mutect2, varscan2
- ATP1A2 | c.2151C>T p.N717= | Silent (SNP) | VAF 48/73 reads (66%) | catalogued as rs140707454, CM078259, COSV63402347, COSV63404669; called by muse, mutect2, varscan2
- CA10 | c.651A>G p.L217= | Silent (SNP) | VAF 3/27 reads (11%) | catalogued as rs1258190111; called by muse, mutect2
- CDKN2AIP | c.540G>T p.G180= | Silent (SNP) | VAF 19/39 reads (49%) | catalogued as COSV100187647; called by muse, mutect2, varscan2
- COL5A1 | c.804C>T p.G268= | Silent (SNP) | VAF 12/29 reads (41%) | catalogued as rs147729713; ClinVar: benign / conflicting interpretations of pathogenicity / uncertain significance; called by muse, mutect2, varscan2
- ELFN1 | c.207G>A p.E69= | Silent (SNP) | VAF 16/53 reads (30%) | catalogued as COSV101300293; called by muse, mutect2, varscan2
- FAM47C | c.1320G>A p.P440= | Silent (SNP) | VAF 24/61 reads (39%) | catalogued as rs782336183, COSV100792752, COSV100792913; called by muse, mutect2, varscan2
- FAT3 | c.12225C>T p.C4075= | Silent (SNP) | VAF 11/29 reads (38%) | catalogued as COSV53099935; called by muse, mutect2, varscan2
- FKBP15 | c.1620A>G p.L540= | Silent (SNP) | VAF 22/49 reads (45%) | catalogued as COSV53033821; called by muse, mutect2, varscan2
- GFAP | c.288G>T p.A96= | Silent (SNP) | VAF 20/30 reads (67%) | catalogued as COSV53650306, COSV99493416; called by muse, mutect2, varscan2
- KATNA1 | c.1284G>A p.A428= | Silent (SNP) | VAF 8/36 reads (22%) | catalogued as rs750453853, COSV100167871; called by muse, mutect2, varscan2
- KLHL1 | c.702C>T p.S234= | Silent (SNP) | VAF 26/51 reads (51%) | catalogued as rs766173867, COSV64780037; called by muse, mutect2, varscan2
- LRRIQ1 | c.4065T>C p.T1355= | Silent (SNP) | VAF 9/73 reads (12%) | catalogued as COSV101280620; called by muse, mutect2, varscan2
- OR12D3 | c.543G>A p.P181= | Silent (SNP) | VAF 7/21 reads (33%) | catalogued as rs140727609; called by muse, mutect2, varscan2
- OR4C15 | c.642T>G p.L214= (on ENST00000314644; = p.L160= on NM_001001920.2) | Silent (SNP) | VAF 29/115 reads (25%) | catalogued as COSV100115819; called by muse, mutect2, varscan2
- OR56A3 | c.141C>A p.T47= | Silent (SNP) | VAF 9/50 reads (18%) | catalogued as COSV100290287, COSV61569082; called by muse, mutect2, varscan2
- PCDH17 | c.1794G>A p.P598= | Silent (SNP) | VAF 6/28 reads (21%) | catalogued as rs539878283, COSV100931748; called by muse, mutect2, varscan2
- PCDHA7 | c.810C>T p.D270= | Silent (SNP) | VAF 20/87 reads (23%) | called by muse, mutect2, varscan2
- PER1 | c.2577C>G p.P859= | Silent (SNP) | VAF 50/138 reads (36%) | catalogued as COSV100424657; called by muse, mutect2, varscan2
- PKD1L3 | c.3078G>A p.P1026= | Silent (SNP) | VAF 20/66 reads (30%) | catalogued as rs750573789, COSV58665094; called by muse, mutect2, varscan2
- PLVAP | c.1116G>A p.A372= | Silent (SNP) | VAF 5/20 reads (25%) | catalogued as rs535383500, COSV53083209, COSV53086717; called by muse, mutect2, varscan2
- PTPRZ1 | c.5727G>T p.L1909= | Silent (SNP) | VAF 8/22 reads (36%) | catalogued as COSV66434942; called by muse, mutect2, varscan2
- RABGAP1L | c.261G>A p.S87= | Silent (SNP) | VAF 10/96 reads (10%) | catalogued as rs967915710, COSV99271439; called by muse, mutect2, varscan2
- RFTN1 | c.621T>C p.T207= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as COSV100489568; called by muse, mutect2, varscan2
- SART3 | c.2340A>C p.A780= (on ENST00000228284; = p.A762= on NM_014706.4) | Silent (SNP) | VAF 10/38 reads (26%) | catalogued as COSV57206754; called by muse, mutect2, varscan2
- SCTR | c.1074C>T p.F358= | Silent (SNP) | VAF 12/18 reads (67%) | catalogued as rs140245245; called by muse, mutect2, varscan2
- SLC30A1 | c.1197G>A p.V399= | Silent (SNP) | VAF 12/46 reads (26%) | catalogued as COSV65360868; called by muse, mutect2, varscan2
- SLC34A3 | c.615C>T p.V205= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as COSV100746681; called by muse, mutect2
- TENM1 | c.3819C>T p.S1273= | Silent (SNP) | VAF 35/125 reads (28%) | catalogued as COSV100950355; called by muse, mutect2, varscan2
- TLE6 | c.426G>A p.P142= (on ENST00000246112 / NM_001143986.2; = p.P19= on NM_024760.3) | Silent (SNP) | VAF 6/21 reads (29%) | catalogued as rs757907159, COSV99858315; called by muse, mutect2, varscan2
- UNC13A | c.2385G>A p.S795= | Silent (SNP) | VAF 10/23 reads (43%) | catalogued as rs747519476, COSV53193247; called by muse, mutect2, varscan2
- AL132655.6 | chr20:58840319 C>T | 5'Flank (SNP) | VAF 12/29 reads (41%) | catalogued as COSV100005821; called by muse, mutect2, varscan2
- AMER3 | c.*488T>A | 3'UTR (SNP) | VAF 9/44 reads (20%) | catalogued as rs112628043, COSV100366688; called by muse, mutect2, varscan2
- ANKRD34C | c.*1031T>A | 3'UTR (SNP) | VAF 11/29 reads (38%) | catalogued as COSV101409550; called by muse, varscan2
- C2orf91 | n.147C>A | RNA (SNP) | VAF 21/38 reads (55%) | catalogued as rs1351125258, COSV101106435; called by muse, mutect2, varscan2
- DCT | c.1179+7472T>C | Intron (SNP) | VAF 21/74 reads (28%) | catalogued as COSV100986253; called by muse, mutect2, varscan2
- DIRAS2 | c.-32G>A | 5'UTR (SNP) | VAF 6/21 reads (29%) | catalogued as rs779081425, COSV101005811; called by muse, mutect2, varscan2
- NLGN4X | c.473-3316G>T | Intron (SNP) | VAF 22/45 reads (49%) | catalogued as COSV99322573; called by muse, mutect2, varscan2
- PIPSL | n.796C>T | RNA (SNP) | VAF 21/107 reads (20%) | called by muse, mutect2, varscan2
- TRAK1 | c.287-16350T>G | Intron (SNP) | VAF 9/35 reads (26%) | catalogued as COSV100410126; called by muse, mutect2, varscan2
- ZNF623 | c.*713C>G | 3'UTR (SNP) | VAF 26/71 reads (37%) | catalogued as COSV101513571; called by muse, mutect2, varscan2
